Somatic mutation profile of tumor specimen MP2PRT-PARAXR-TMP1-A (aliquot MP2PRT-PARAXR-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARAXR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,436 days).
Specimen MP2PRT-PARAXR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6637ccaa-eda4-45ac-8cf0-e70f763a6616.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARAXR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARAXR-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75f9e508-d6ab-4f2b-aa1b-98a4008aeaf5

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPAMD8 | c.3748C>T p.R1250W (on ENST00000651564; = p.R1203W on NM_015692.5) | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1183335225; called by muse, mutect2, varscan2
- SULT1C2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 66/198 reads (33%) | catalogued as rs1191499679, COSV52267739; called by muse, mutect2, varscan2
- ZBTB3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67361802; called by muse, mutect2, varscan2
- ARHGAP21 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 145/399 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TENT5D | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 114/350 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- TTN | c.43347C>T p.Y14449= (on ENST00000591111; = p.Y7025= on NM_003319.4) | Silent (SNP) | VAF 100/343 reads (29%) | catalogued as rs397517592, COSV60156233; ClinVar: likely benign; called by muse, mutect2, varscan2
